FM case AD9345 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/f96a2460-76b2-45a6-9d79-19663bc73f0b

Female, 40.2 years: Carcinoma, NOS (ICD-O-3 8010/3) of the breast; primary biopsied or resected from the breast. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
